Surgical pathology report (de-identified scan), TCGA case TCGA-BF-A1PU, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Cureline, specimen TCGA-BF-A1PU-01A (Primary Tumor).

Project #
TSS

ICB-0-3
Melanoma, NOS 8720/3
Site: Skin, NOS C44.9 3/12/11 *lw*

Index	Specimen label	Clinical Site #	Case #	Ethnicity (Race)	Clinical Diagnosis	DOB (mm/dd/yyyy)	Sex	Date of procurement	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format
1		5		Caucasian (White)	Melanoma		Female		Skin	Primary	Tumor	Tissue	Frozen
		5		Caucasian (White)	Melanoma		Female		Blood	n/a	normal	Blood	Frozen

Container	Number of containers	Amount/per container	Unit	Type of Procurement	Histological description	Grade	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Prior Chemo / Hormonal Th	Chemo / Horm Th Details	Prior Radiation	Cellular Tumor %
cryomold	1	200	mg	Surgery	Melanoma	n/a	2a	0	0	no	no	no	85
tube	1	4	ml	Blood draw	n/a	n/a	n/a	n/a	n/a	no	no	no	n/a

Diagnosis Discrepancy		K
Primary Tumor Site Discrepancy		K
HiPA Discrepancy		K
Prior Malignancy History		K

Source: NCI Genomic Data Commons file a05b7769-2e7b-422a-aa88-dd2a145d84f9 (TCGA-BF-A1PU.D6618B79-299C-4EDB-8EC4-7AFC61D6E460.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).